Gene-level copy-number profile of tumor specimen TCGA-OR-A5J9-01A from TCGA case TCGA-OR-A5J9, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 22.4 years (8,175 days).
Specimen TCGA-OR-A5J9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.726707fb-2431-4598-a72d-57bb4467eb0c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5J9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a12f2c95-6322-46cc-ae7a-4835dc9336ed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 5,607; copy number 3: 3; copy number 4: 28,268; copy number 6: 15,282; copy number 7: 99; copy number 8: 8,643; copy number 9: 324; copy number 11: 1,543; copy number 12: 16; copy number 13: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5J9-01A-11D-A29H-01): tumor purity 0.84, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:28,883,572–29,057,488, 2 genes (within-gene range 0–2): ZNRF3, ZNRF3-IT1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,911 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–49,062,081, 728 genes, copy number 11 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 9–11 (broad region; genes not listed).
- chr14:20,239,286–27,295,516, 392 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr14:28,726,675–29,500,460, 16 genes, copy number 12: FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P.
- chr14:43,274,824–44,393,716, 11 genes, copy number 9: TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1.
- chr14:45,369,215–46,501,903, 6 genes, copy number 9: AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871.
- chr14:67,619,920–69,483,714, 48 genes, copy number 9–13: ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3, BANF1P1, ACTN1-AS1, RPS29P1, DCAF5, DDX18P1, Y_RNA, AL391262.1, AL359317.2, EXD2, AL359317.1, GALNT16, AL157996.1, ERH, SLC39A9, AL157996.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
